MMRF case MMRF_1157 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/56ed99a7-42bb-46a1-acd9-c66733fece55

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.8 years (25,484 days); ISS stage: I; Days to last known disease status: 1,683 days (4.6 years); Days to last follow up: 1,683 days (4.6 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 156 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 240 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 222 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 240 days; Days to treatment end: 240 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 240 days; Days to treatment end: 240 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 326 days; Days to treatment end: 442 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 415 days (1.1 years); Days to treatment end: 527 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 415 days (1.1 years); Days to treatment end: 556 days (1.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 591 days (1.6 years); Days to treatment end: 682 days (1.9 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 598 days (1.6 years); Days to treatment end: 682 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 682 days (1.9 years); Days to treatment end: 921 days (2.5 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 960 days (2.6 years); Days to treatment end: 1,578 days (4.3 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 960 days (2.6 years); Days to treatment end: 969 days (2.7 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 990 days (2.7 years); Days to treatment end: 1,578 days (4.3 years).
   Treatment given: Therapeutic agents: Dexamethasone + Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,626 days (4.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 97.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.064 mg/dL; Immunoglobulin G 6.65 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L; C-Reactive Protein 0.56 mg/dL.
- Day 93 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.073 mg/dL; Immunoglobulin G 5.8 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 4.79 mmol/L.
- Day 184 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.076 mg/dL; Immunoglobulin G 4.82 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.84 mmol/L.
- Day 262 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 5.72 mmol/L.
- Day 353 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.861 mg/dL; Immunoglobulin G 7.88 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 44 g/L; Glucose 5.72 mmol/L.
- Day 443 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 7.64 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 534 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.
- Day 576 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.122 mg/dL; Immunoglobulin G 7.68 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 5.01 mmol/L.
- Day 675 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 114 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.083 mg/dL; Immunoglobulin G 4.51 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.71 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 794 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 83.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 3.06 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 4.58 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 877 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 45.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 2.58 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.98 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.01 mmol/L.
- Day 933 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 138 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.046 mg/dL; Immunoglobulin G 2.99 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.28 µg/mL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.62 mmol/L.
- Day 1,088 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.516 mg/dL; Immunoglobulin G 3.77 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.44 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 5.06 mmol/L.
- Day 1,158 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.053 mg/dL; Immunoglobulin G 3.15 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 363 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 1,242 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 2.69 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 5.17 mmol/L.
- Day 1,326 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.074 mg/dL; Immunoglobulin G 2.48 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 360 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 5.23 mmol/L.
- Day 1,410 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.065 mg/dL; Immunoglobulin G 2.24 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 363 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.
- Day 1,494: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.046 mg/dL; Immunoglobulin G 1.72 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 332 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.55 mmol/L; Albumin 40 g/L; Total Protein 5.4 g/dL; Glucose 4.73 mmol/L.
- Day 1,626 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 26.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.099 mg/dL; Immunoglobulin G 1.61 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.95 mmol/L.
- Day 1,683 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 1.46 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 4.82 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 44 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day -13: Weight: 64 kg; Height: 156 cm.

Biospecimens (6 samples)
- Sample MMRF_1157_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1157_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
- Sample MMRF_1157_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 576 days (1.6 years).
- Sample MMRF_1157_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 675 days (1.8 years).
- Sample MMRF_1157_3_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 675 days (1.8 years).
- Sample MMRF_1157_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 933 days (2.6 years).
